CCDI case PBCHIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/fd7e4830-b009-4ae8-96e6-3852f7a1a5d0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pancreatoblastoma: ICD-O-3 morphology code: 8971/3; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 7.3 years (2,676 days).

Biospecimens (3 samples)
- Sample 0DSP20: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSP26: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSP2G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
